Gene-level copy-number profile of tumor specimen TCGA-EQ-8122-01A from TCGA case TCGA-EQ-8122, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.0 years (26,289 days).
Specimen TCGA-EQ-8122-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.707b0b55-849f-447f-8d0b-1bbd398f8755.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EQ-8122-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29e317eb-1059-41f2-81a9-165da3f8600f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 2: 1,110; copy number 3: 21,051; copy number 4: 7,403; copy number 5: 12,736; copy number 6: 6,544; copy number 7: 7,206; copy number 8: 2,013; copy number 9: 54; copy number 10: 774; copy number 11: 378; copy number 12: 205; copy number 13: 18; copy number 14: 15; copy number 15: 118; copy number 20: 12; copy number 21: 83; copy number 37: 72; copy number 55: 4; copy number 74: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EQ-8122-01A-11D-2338-01): tumor purity 0.47, ploidy 4.3, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 10,965 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–220,468,808, 1,919 genes, copy number 7 (broad region; genes not listed).
- chr1:223,220,819–247,257,210, 546 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:62,463,127–63,046,487, 12 genes, copy number 7 (within-gene range 5–7): AC093159.1, RN7SL18P, TMEM17, RPL37P13, RPL21P37, AC092155.1, PSAT1P2, RSL24D1P2, EHBP1, Y_RNA, AC092567.2, AC092567.1.
- chr3:128,538,020–130,035,539, 64 genes, copy number 7 (broad region; genes not listed).
- chr5:4,451,930–4,866,311, 1 gene, copy number 7 (within-gene range 4–7): AC106799.2.
- chr5:4,773,481–11,904,446, 143 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:12,794,100–18,746,173, 100 genes, copy number 7 (broad region; genes not listed).
- chr6:41,149,342–170,738,536, 1,880 genes, copy number 7–11 (broad region; genes not listed).
- chr7:131,110,096–131,496,632, 1 gene, copy number 8 (within-gene range 5–8): MKLN1.
- chr7:131,309,469–131,754,252, 8 genes, copy number 8: MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2.
- chr8:72,429,620–145,066,685, 1,141 genes, copy number 7–9 (broad region; genes not listed).
- chr10:2,936,021–35,090,642, 556 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).
- chr11:65,823,022–135,075,908, 1,574 genes, copy number 7 (broad region; genes not listed).
- chr13:44,094,822–44,577,147, 13 genes, copy number 8 (within-gene range 5–8): LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2, TUSC8, TSC22D1, AL138960.2, AL139184.1.
- chr16:64,943,753–79,212,667, 437 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr16:79,105,957–90,222,851, 315 genes, copy number 8 (broad region; genes not listed).
- chr17:27,002,661–31,831,750, 255 genes, copy number 10–14 (broad region; genes not listed).
- chr17:33,013,087–39,747,291, 258 genes, copy number 7–55 (broad region; genes not listed).
- chr17:40,516,892–46,268,694, 356 genes, copy number 10–74 (broad region; genes not listed).
- chr17:51,336,646–51,521,401, 2 genes, copy number 10 (within-gene range 5–10): LINC02073, RPL7P48.
- chr17:55,751,051–55,872,939, 2 genes, copy number 10: PCTP, AC090618.1.
- chr17:60,392,429–64,662,307, 137 genes, copy number 11 (broad region; genes not listed).
- chr17:70,628,917–75,757,818, 128 genes, copy number 10–13 (within-gene range 3–13) (broad region; genes not listed).
- chr20:87,250–8,999,100, 218 genes, copy number 7 (broad region; genes not listed).
- chr20:30,214,765–64,313,132, 899 genes, copy number 8–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
